Surgical pathology report (de-identified scan), TCGA case TCGA-ZN-A9VS, project TCGA-MESO (Mesothelioma), tissue source site Brigham and Women's Hospital Division of Thoracic Surgery, specimen TCGA-ZN-A9VS-01A (Primary Tumor).

[page 1 of 5]
Pathology Report

Report Status: Amend/Addenda

Procedure Date: [REDACTED]

***** Added Report *****

PATHOLOGIC DIAGNOSIS:

- A. RIB (18.9 CM), MARROW SQUEEZE:
Maturing trilineage hematopoiesis, negative for tumor.
- B. CHEST WALL TUMOR:
MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE, invading fibrous connective tissue.
- C. PERICARDIAL MASS:
Adipose tissue with MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE.
- D. LEVEL 9 LN:
See part L.
- E. PARIETAL PLEURA:
Fragments of pleura with MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE.
Hyaline plaque.
- F. NODE FROM PHRENIC:
See part L.
- G. TUMOR ON PHRENIC:
Nerve and attached fibroadipose tissue, negative for tumor.
Artery with medial calcification.
- H. LEVEL 10 LYMPH NODE:
Two (2) lymph nodes, negative for tumor.
- I. DIAPHRAGM:
MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE, involving pericardium and pleura attached to diaphragm, without invasion of diaphragmatic muscle, approaching <0.1 cm from the anterior and medial diaphragmatic resection margins.
Hyaline plaque.
- J. LEVEL 7 LYMPH NODE:
Two (2) lymph nodes, negative for tumor.
- K. LEVEL 8 LYMPH NODE:
Three (3) lymph nodes, negative for tumor.
- L. RIGHT LUNG, PERICARDIUM, VISCERAL AND PARIETAL PLEURA:
DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE .
Tumor involves: chest wall parietal pleura, maximal thickness of 1.7 cm, mediastinal pleura, and diaphragmatic pleura.
Tumor invades: lung parenchyma, mediastinal adipose tissue, soft tissue, chest wall in multiple foci (see part B), pericardium and does NOT extend to the inner surface of the pericardium, see part C).
Tumor is <0.1 cm from anterior and medial diaphragmatic resection margins.
Lymphovascular invasion is not identified.
Hyalin pleural plaque is identified (parts E and I).
Pulmonary emphysema is present.

ICD O-3
Mesothelioma, epithelioid,
malignant 9852/3
Site: R Pleura NOS C38.4
JW 6/13/14

[page 2 of 5]
Pathology Report

Immunohistochemical studies were performed on the original biopsy material

Eleven (11) lymph nodes with no tumor present (additional lymph nodes in parts D, F, H, J, K, and M also negative for tumor).

AJCC Classification (7th edition): pT3 N0 MX.

M. INTERNAL MAMMARY NODE:

One (1) lymph node, negative for tumor.
See part L.

N. PORT SITE 1:

Skin and subcutis with cicatrix, negative for tumor.
See part L.

O. PORT SITE 2:

Skin and subcutis with cicatrix, negative for tumor.
See part L.

TISSUE SUBMITTED:

A/1. Rib.
B/2. Chest wall tumor.
C/3. Pericardial mass.
D/4. Level 9 LN.
E/5. Parietal pleura.
F/6. Node from phrenic.
G/7. Tumor on phrenic.
H/8. Level 10 lymph node.
I/9. Diaphragm.
J/10. Level 7 lymph node.
K/11. Level 8 lymph node.
L/12. Right lung pericardium.
M/13. Internal mammary node.
N/14. Port site #1.
O/15. Port site #2.

GROSS DESCRIPTION:

The specimen is received fresh, in fifteen separate containers, each labeled with the patient's name, medical record number and specimen identification.

Part A, "#1. Rib", consists of a segment of grossly unremarkable rib (18.9 x 1.5 x 0.4 cm). A rib marrow squeeze is prepared and submitted for histologic analysis as follows:

Micro A1: Rib squeeze bone marrow, 1 frag, RSS.

Part B, "#2. Chest wall biopsy", consists of a firm white fibrotic nodule (1.7 x 1.3 x 1.0 cm) with attached soft tissue. The specimen is submitted for histologic analysis as follows:

Micro B1: Chest wall biopsy, 1 frag, RSS.

Part C, "#3. Pericardial mass", consists of two fibroadipose soft tissue fragments (2.4 x 1.5 x 0.3 cm in aggregate), submitted for histologic analysis as follows:

Micro C1: Pericardial mass, 2 frags, ESS.

Part D, "#4. Level 9 lymph node", consists of a single anthracotic lymph node candidate (1.4 x 0.9 x 0.4 cm), submitted for histologic analysis as follows:

[page 3 of 5]
Pathology Report

Micro D1: Single lymph node candidate, bisected, 2 frags, ESS.

Part E, "#5. Parietal pleura", consists of multiple fragments of firm fibrotic and hemorrhagic soft tissue (7.0 x 4.2 x 2.5 cm in aggregate), submitted for histologic analysis as follows:

Micro E1-E2: Representative sections of the soft tissue fragments, 5 frags, RSS.

Part F, "#6. Node from phrenic", consists of an anthracotic lymph node candidate (1.2 x 0.6 x 0.4 cm) with attached fibroadipose tissue. The specimen is submitted for histologic analysis as follows:

Micro F1: Anthracotic lymph node candidate, bisected, 2 frags, ESS.

Part G, "#7. Tumor on phrenic", consists of a long white cylindrical soft tissue fragment (11.0 x 0.3 cm in diameter) with attached yellow fibroadipose tissue.

Micro G1-G2: phrenic nerve, multi frags, ESS.

Part H, "#8. Level 10 lymph node", consists of fibroadipose tissue containing two lymph node candidates (1.1 x 0.6 x 0.4 and 0.2 x 0.2 x 0.2 cm respectively). The specimen is submitted for histologic analysis as follows:

Micro H1: 2 lymph node candidates, the largest of which is bisected, 3 frags, ESS.

Part I, "#9. Diaphragm", consists of a portion of diaphragm (17.5 x 12 with thickness ranging from 0.5 to 2.5 cm) remarkable for multiple white fibrotic nodules involving the attachment of the pericardium to the diaphragm as well as several that are located adjacent to the resection margin on the thoracic surface of the diaphragm. There is no grossly evident disease on the abdominal surface of the diaphragm. The abdominal surface is inked black and the specimen is sectioned and submitted for histologic analysis as follows:

Micro I1-I2: Representative section of the largest nodule involving the attachment of the pericardium to the thoracic surface of the diaphragm, 2 frags, RSS.

Micro I3 through I4: Representative sections of other nodules on the thoracic surface of the diaphragm, 4 frags, RSS.

Micro I5: Representative sections of a relatively uninvolved portion of the pericardium, 2 frags, RSS.

Part J, "#10. Level 7 lymph node", consists of a darkly anthracotic lymph node candidate (1.2 x 1.0 x 0.5 cm), submitted for histologic analysis as follows:

Micro J1: 1 lymph node, 2 frags, ESS.

Part K, "#11. Level 8 lymph node", consists of a fibroadipose soft tissue fragment, highly irregular in shape with no definitive lymph node candidates (2.5 cm x 2.0 x 0.4 cm), submitted for histologic analysis as follows:

Micro K1: Fibroadipose tissue, bisected, 2 frags, ESS.

Part L, "#12. Right lung, pericardium, visceral and parietal pleura", consists of a 752 gram extrapleural pneumonectomy specimen (21.5 x 18.8 x 2.8 cm) with a segment of bronchus (2.5 cm in length x 2.7 cm in diameter), and a fragment of pericardium (5.1 x 3.9 x 0.2 cm) on the medial aspect of the specimen. The lateral aspect of the specimen is severely disrupted (visceral pleura appears to have been stripped off) and presents with a single staple line (7.5 cm, only partially attached along, inked blue where attached along). No diaphragm is present (see part I above). Multiple firm, ill-defined nodules (ranging from 0.5 to 4.2 cm in greatest dimension) are located in areas of fusion between the visceral and parietal pleura and affect approximately 75% of the visceral and parietal pleura, including mediastinal diaphragmatic, anterior, posterior, lateral, superior. A representative section of nodule is submitted for

[page 4 of 5]
Pathology Report

A representative section of normal is submitted to tissue bank. There are four approximately 1 cm sized lymph nodes around the bronchus and many intrapulmonary lymph nodes which have an anthracotic and somewhat partially white fibrous parenchyma. The majority of the parenchyma appears grossly uninvolved by tumor and/or other obvious pulmonary pathology. There is; however, two foci of possible invasion of mesothelioma into the lung parenchyma present in the right middle and right lower pulmonary lobes. A portion of uninvolved lung is submitted to

The specimen is submitted for histologic analysis

as follows:

Micro L1: En face bronchial resection margin, 1 frag, ESS.

Micro L2: Section of largest nodule in the right lower lobe, adjacent to the sample taken for electron microscopy and ancillary studies, 1 frag, RSS.

Micro L3: Nodule from the medial surface of the lung with fusion of the visceral and parietal pleura and possible invasion into lung parenchyma, 1 frag, RSS.

Micro L4-L5: Representative sections of pleural nodules, multi frags, RSS.

Micro L6-L7: Representative section of the largest nodule in the right lower lobe to include the surface and the interface with normal lung parenchyma, 2 frags, RSS.

Micro L8: Representative section of the nodule in the right middle lobe with possible invasion to lung parenchyma, 1 frag, RSS.

Micro L9: 4 peribronchial lymph node candidates, intact, 4 frags, ESS.

Micro L10: 4 intrapulmonary (peribronchiolar) lymph node candidates, 4 frags, RSS.

Part M, "#13. Internal mammary node", consists of three fragments of fibroadipose tissue with one containing a possible lymph node candidate (2.5 x 2.2 x 0.7 cm in aggregate) submitted for histologic analysis as follows:

Micro M1: Internal mammary node, 3 frags, ESS.

Part N, "#14. Port site #1", consists of an ellipse of skin (4.0 cm in length x 1.2 cm in width) with an eccentrically located scar (2.2 cm in length, well healed excised to a depth of 0.9 cm of subcutis). Serial sectioning reveals no gross evidence of disease. The entire scar is submitted for histologic analysis as follows:

Micro N1: Entire scar, 6 frags, ESS.

Part O, "#15. Port site #2", consists of an ellipse of skin (2.6 cm x 1.1 cm in width, excised to a depth of 1.1 cm) with an eccentrically located scar (1.0 cm in length), submitted for histologic analysis as follows:

Micro O: Port site #2, 5 frags, ESS.

Note: For part I, the nodules do not grossly appear to invade the diaphragm. Smaller nodules are located close (0.3 cm from the anterior and medial diaphragm resection margins) and micro I6 closest approach to the anterior and medial resection margin, 2 frags, RSS.

senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[page 5 of 5]
Pathology Report

[Redacted]

Lung Digestion for Asbestos Quantification:

1.88 grams of lung tissue were digested. 439 asbestos bodies per gram of lung tissue (wet weight) were found. (General population median: 20).

[Redacted]

Source: NCI Genomic Data Commons file 8edc47bf-84c7-46c4-b1e5-28c0cc8bb312 (TCGA-ZN-A9VS.B47307E4-CEA2-4965-BAE9-16184AFFC8BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).